Somatic mutation profile of tumor specimen TCGA-64-5781-01A (aliquot TCGA-64-5781-01A-01D-1625-08) from TCGA case TCGA-64-5781, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 55.4 years (20,219 days).
Specimen TCGA-64-5781-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9088478f-0a26-44e3-af3c-ec2c80bbae26.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-64-5781-10A (Blood Derived Normal), aliquot TCGA-64-5781-10A-01D-1625-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1c932ec8-5d1f-4a48-9dbe-cc61c6dd93bb

The open-access MAF lists 1,197 somatic variants for this specimen: 912 protein-altering or splice-affecting, 262 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 767, Silent 262, Nonsense Mutation 74, Frame Shift Del 31, Splice Site 19, Frame Shift Ins 12, RNA 9, Splice Region 8, Intron 8, 5'UTR 3, 3'Flank 3, In Frame Del 1.

Variants (750 of 1,197; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TUBB4A | c.1091C>A p.A364D | Missense Mutation (SNP) | VAF 56/164 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.673); catalogued as rs886041017, CM151583, COSV51168409, COSV99900050; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2M | c.3970C>A p.L1324I | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.081); catalogued as COSV59393108; called by muse, mutect2, varscan2
- AASDHPPT | c.770C>T p.P257L | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV53790700; called by muse, mutect2, varscan2
- ABCA10 | c.3977C>T p.A1326V | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.654); catalogued as COSV52230498; called by muse, mutect2
- ABCA12 | c.647C>G p.T216S | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV55977700; called by muse, mutect2, varscan2
- ABCA2 | c.6209G>T p.R2070L (on ENST00000614293; = p.R2040L on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55803163, COSV55807400; called by muse, mutect2, varscan2
- ABCA5 | c.218C>T p.T73I | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV67019359; called by muse, mutect2
- ABCB5 | c.1804G>T p.E602* (on ENST00000404938 / NM_001163941.2; = p.E157* on NM_178559.6) | Nonsense Mutation (SNP) | VAF 19/84 reads (23%) | catalogued as COSV51722201; called by muse, mutect2, varscan2
- ABCC10 | c.4422C>A p.F1474L (on ENST00000372530 / NM_001198934.2; = p.F1446L on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV55094483, COSV55094551; called by muse, mutect2, varscan2
- ABCC11 | c.776A>T p.E259V | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV62326188; called by muse, mutect2
- ABCC2 | c.3361C>A p.P1121T | Missense Mutation (SNP) | VAF 18/171 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64988791; called by muse, mutect2
- ABCC5 | c.4183G>T p.D1395Y | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55597054; called by muse, mutect2, varscan2
- ABCC9 | c.1868A>C p.E623A | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV53988032; called by muse, mutect2, varscan2
- ABHD10 | c.36G>C p.W12C | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.417); catalogued as COSV56326549; called by muse, mutect2, varscan2
- ABLIM3 | c.546C>A p.S182R | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.22); catalogued as COSV58646703; called by muse, mutect2, varscan2
- ACE | c.3218G>T p.R1073L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs141139841, COSV52013779; called by mutect2, varscan2
- ACOT6 | c.292G>C p.E98Q | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV66969252; called by muse, mutect2, varscan2
- ACSM1 | c.1218C>A p.S406R | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.131); catalogued as COSV54640627; called by muse, mutect2, varscan2
- ACSM5 | c.487del p.A163Pfs*10 | Frame Shift Del (DEL) | VAF 5/36 reads (14%) | catalogued as COSV59372480; called by mutect2, pindel, varscan2
- ACSS3 | c.728A>T p.K243I | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV54102444; called by muse, mutect2, varscan2
- ACTC1 | c.908G>T p.G303V | Missense Mutation (SNP) | VAF 45/138 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1057518530, COSV51761886; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACTG1 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV59512263; called by muse, mutect2, varscan2
- ACTL9 | c.925G>T p.G309W | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61007372; called by muse, mutect2, varscan2
- ACTRT2 | c.1057A>T p.S353C | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV65760686; called by muse, mutect2, varscan2
- ADAM9 | c.1327G>T p.E443* | Nonsense Mutation (SNP) | VAF 6/65 reads (9%) | catalogued as COSV101166311, COSV65962805; called by muse, mutect2, varscan2
- ADAMTS12 | c.1505C>A p.S502Y | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV61281780; called by muse, mutect2, varscan2
- ADAMTS12 | c.1378G>T p.G460C | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.775); catalogued as COSV61275700; called by muse, varscan2
- ADAMTS12 | c.623G>A p.C208Y | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as COSV61281804; called by muse, mutect2, varscan2
- ADAMTS15 | c.2239G>T p.E747* | Nonsense Mutation (SNP) | VAF 8/59 reads (14%) | catalogued as COSV54510226; called by muse, mutect2, varscan2
- ADAMTS20 | c.2849G>T p.G950V | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as COSV67140509; called by muse, mutect2
- ADCY1 | c.2539C>T p.Q847* | Nonsense Mutation (SNP) | VAF 5/25 reads (20%) | catalogued as COSV52043419; called by muse, mutect2, varscan2
- ADCY10 | c.4048A>T p.S1350C | Missense Mutation (SNP) | VAF 24/190 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV63245459; called by muse, mutect2, varscan2
- ADCY6 | c.1586A>T p.E529V | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.527); catalogued as COSV57170945; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.680A>T p.K227M | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58447591; called by muse, mutect2, varscan2
- ADGRG4 | c.3491C>A p.T1164N | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99797117; called by muse, mutect2, varscan2
- ADGRL2 | c.1793G>T p.R598L | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54683574, COSV54689423; called by muse, mutect2, varscan2
- ADGRL3 | c.2839G>T p.V947L (on ENST00000506720 / NM_001322402.2; = p.V879L on NM_015236.6) | Missense Mutation (SNP) | VAF 43/207 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.517); catalogued as COSV72231244, COSV72231859, COSV72232087; called by muse, mutect2, varscan2
- AEBP1 | c.3079C>A p.L1027M | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.024); catalogued as COSV56261654; called by muse, mutect2, varscan2
- AEN | c.295C>T p.P99S | Missense Mutation (SNP) | VAF 28/46 reads (61%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV60430398; called by muse, mutect2, varscan2
- AGMO | c.270G>C p.R90S | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as COSV100694909, COSV61125179; called by muse, mutect2, varscan2
- AGMO | c.25G>T p.D9Y | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as rs773679678, COSV61122133, COSV61125185; called by muse, mutect2, varscan2
- AGO2 | c.910G>A p.V304M | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV55053279; called by muse, mutect2, varscan2
- AHNAK | c.14330A>T p.H4777L | Missense Mutation (SNP) | VAF 40/226 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV57232966; called by muse, mutect2, varscan2
- AHNAK | c.789G>T p.K263N | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57232981; called by muse, mutect2, varscan2
- AJUBA | c.895G>T p.G299* | Nonsense Mutation (SNP) | VAF 6/26 reads (23%) | catalogued as rs1283169377, COSV52986901; called by muse, mutect2, varscan2
- ALDOC | c.272G>T p.G91V | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs960227395, COSV99257332; called by muse, mutect2, varscan2
- ALK | c.4425C>A p.H1475Q | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); catalogued as rs139039449, COSV66591681; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AMELX | c.223C>A p.P75T | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.15); catalogued as COSV100496984, COSV61636707; called by muse, mutect2, varscan2
- AMER2 | c.97G>A p.G33R | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.312); catalogued as rs747561489, COSV63440587; called by muse, varscan2
- AMY1C | c.992G>A p.W331* | Nonsense Mutation (SNP) | VAF 39/385 reads (10%) | catalogued as rs749260652, COSV64407624; called by muse, mutect2, varscan2
- ANGPT1 | c.891T>A p.S297R | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV52458580; called by muse, mutect2, varscan2
- ANGPTL5 | c.850G>T p.D284Y | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100528035; called by muse, varscan2
- ANK1 | c.1021C>A p.P341T | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as COSV55897520, COSV99225903; called by muse, mutect2, varscan2
- ANK3 | c.5370G>T p.Q1790H | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.594); catalogued as COSV55044165, COSV55084821; called by muse, mutect2, varscan2
- ANKFN1 | c.1017+1del | Frame Shift Del (DEL) | VAF 11/57 reads (19%) | catalogued as COSV100592935, COSV59453180; called by mutect2, pindel, varscan2
- ANKRD26 | c.4507G>T p.A1503S | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.037); catalogued as rs1025942290, COSV65778780; called by muse, mutect2, varscan2
- ANKRD42 | c.829G>T p.A277S | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1490587337, COSV52618755; called by muse, mutect2, varscan2
- AOC3 | c.1092C>A p.S364R | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53828994; called by muse, mutect2, varscan2
- AP5M1 | c.1223C>A p.T408N | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.011); catalogued as COSV99841391; called by muse, mutect2, varscan2
- APOB | c.11809G>A p.E3937K | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as rs766656064, COSV51925162; called by muse, mutect2, varscan2
- APOB | c.8774G>T p.G2925V | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51955081; called by muse, mutect2, varscan2
- APOB | c.5281G>A p.G1761S | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV51955094; called by muse, mutect2, varscan2
- APOL3 | c.134G>A p.G45D | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as COSV62580945; called by muse, mutect2, varscan2
- AQP10 | c.782A>T p.Q261L | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV59248200; called by muse, mutect2, varscan2
- AQP6 | c.708C>G p.F236L | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.061); catalogued as COSV100210299; called by muse, mutect2, varscan2
- ARHGAP12 | c.2081G>T p.S694I | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100260958; called by muse, mutect2
- ARHGAP21 | c.5197G>T p.V1733L | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as COSV57605291, COSV57611755; called by muse, mutect2, varscan2
- ARHGAP25 | c.1093C>A p.P365T (on ENST00000409202 / NM_001007231.3; = p.P357T on NM_014882.3) | Missense Mutation (SNP) | VAF 35/144 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.122); catalogued as COSV54909915; called by muse, mutect2, varscan2
- ARHGAP35 | c.4184A>G p.N1395S | Missense Mutation (SNP) | VAF 76/166 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV68336092; called by muse, mutect2, varscan2
- ARHGAP6 | c.1739G>T p.R580L | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV57304162; called by muse, mutect2, varscan2
- ASIC2 | c.1366G>T p.E456* | Nonsense Mutation (SNP) | VAF 4/30 reads (13%) | catalogued as COSV56771823, COSV99861276; called by muse, mutect2
- ASPM | c.8402C>T p.S2801F | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.514); catalogued as COSV54139896; called by muse, mutect2, varscan2
- ASTL | c.734G>T p.R245L | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.23); catalogued as COSV60905632; called by muse, mutect2, varscan2
- ASTN2 | c.1768G>T p.G590C (on ENST00000313400 / NM_001365069.1; = p.G539C on NM_014010.5) | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57821146; called by muse, varscan2
- ASXL2 | c.576G>T p.Q192H | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV55468803; called by muse, mutect2, varscan2
- ATF6 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.012); catalogued as rs1300329534, COSV63410403; called by muse, mutect2, varscan2
- ATP2B2 | c.661C>A p.L221I | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.992); catalogued as COSV100660568; called by muse, mutect2
- ATP6V1H | c.642C>G p.Y214* | Nonsense Mutation (SNP) | VAF 8/29 reads (28%) | catalogued as COSV62220715; called by muse, mutect2, varscan2
- ATRIP | c.1189G>A p.D397N | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV56498195; called by muse, mutect2, varscan2
- B4GAT1 | c.514G>T p.E172* | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | catalogued as rs761732914, COSV60820821, COSV60820969; called by mutect2, varscan2
- BCAR1 | c.1983G>T p.M661I | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV50807210; called by muse, mutect2
- BCL11A | c.911C>T p.P304L (on ENST00000335712 / NM_001365609.1; = p.P338L on NM_018014.4) | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100186662, COSV59628062; called by muse, mutect2, varscan2
- BCL11A | c.910C>T p.P304S (on ENST00000335712 / NM_001365609.1; = p.P338S on NM_018014.4) | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100186663, COSV59630288; called by muse, mutect2, varscan2
- BCL9L | c.2938G>T p.G980C | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as COSV99420263; called by muse, mutect2, varscan2
- BCO2 | c.642G>T p.W214C | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63065174; called by muse, mutect2, varscan2
- BCR | c.923G>T p.R308L | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0); catalogued as rs750811897, COSV100007158; called by muse, mutect2
- BEND2 | c.1918G>C p.A640P | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.311); catalogued as COSV66217493, COSV66217675; called by muse, mutect2, varscan2
- BGN | c.884G>C p.G295A | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781916886, COSV59038612; called by muse, mutect2
- BICC1 | c.1502C>T p.P501L | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.101); catalogued as COSV54065267; called by muse, mutect2, varscan2
- BIRC3 | c.1198C>T p.Q400* | Nonsense Mutation (SNP) | VAF 10/64 reads (16%) | catalogued as COSV54820198; called by muse, varscan2
- BMP1 | c.2566C>T p.H856Y | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.107); catalogued as COSV100115033, COSV60535642; called by muse, mutect2, varscan2
- BOD1L1 | c.3796G>T p.A1266S | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.009); catalogued as COSV50078363; called by muse, mutect2, varscan2
- BPIFB2 | c.431C>A p.A144D | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV50071447; called by muse, mutect2, varscan2
- BTBD10 | c.943G>A p.D315N | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.481); catalogued as COSV53401926; called by muse, mutect2, varscan2
- BTBD11 | c.2330C>G p.T777R (on ENST00000280758 / NM_001018072.2; = p.T314R on NM_001017523.2) | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as rs764451250, COSV55039024, COSV55041010; called by mutect2, varscan2
- BUB1B | c.238A>T p.R80W | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55017204; called by muse, mutect2, varscan2
- C11orf80 | c.1575T>A p.D525E | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100547199; called by muse, mutect2, varscan2
- C1GALT1 | c.896G>T p.G299V | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.042); catalogued as COSV56179585; called by muse, mutect2, varscan2
- C1QC | c.326G>T p.G109V | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101009561; called by muse, mutect2, varscan2
- C8orf74 | c.511C>G p.L171V | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776713924, COSV58755722; called by mutect2, varscan2
- C9 | c.1298C>G p.T433S | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.083); catalogued as COSV54682076; called by muse, mutect2
- CA10 | c.157G>A p.V53M | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99565486; called by muse, mutect2, varscan2
- CACNA1B | c.4270G>A p.D1424N | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); catalogued as COSV53151336; called by muse, mutect2, varscan2
- CACNA1E | c.1168G>C p.A390P | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV62384980, COSV62432051; called by muse, mutect2
- CALHM5 | c.781G>T p.A261S | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.998); catalogued as COSV62068777; called by muse, mutect2, varscan2
- CAPN11 | c.1067G>T p.G356V | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67239723; called by muse, mutect2, varscan2
- CAPRIN2 | c.1081C>T p.Q361* | Nonsense Mutation (SNP) | VAF 6/39 reads (15%) | catalogued as COSV51836000; called by muse, mutect2, varscan2
- CARD11 | c.481G>T p.D161Y | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV62716677, COSV62717275; called by muse, mutect2, varscan2
- CASR | c.2819A>T p.Q940L (on ENST00000490131; = p.Q1017L on NM_000388.4) | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); catalogued as COSV56141853; called by muse, mutect2
- CCDC113 | c.579T>A p.N193K | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV54687933, COSV54688098; called by muse, mutect2, varscan2
- CCNT2 | c.1634G>A p.S545N | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.276); catalogued as rs1386784271, COSV99751284; called by muse, mutect2
- CCR4 | c.901C>A p.P301T | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100447551, COSV58381359; called by muse, mutect2, varscan2
- CD1C | c.289C>G p.R97G | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.714); catalogued as COSV63807818; called by muse, mutect2, varscan2
- CD1C | c.594G>A p.M198I | Missense Mutation (SNP) | VAF 52/358 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1173131689, COSV63806555, COSV63807823; called by muse, mutect2, varscan2
- CD1E | c.998+1G>T p.X333_splice | Splice Site (SNP) | VAF 8/45 reads (18%) | catalogued as COSV100937081, COSV63771855; called by muse, mutect2, varscan2
- CD3D | c.450G>C p.Q150H | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1303060867, COSV52676402; called by muse, mutect2, varscan2
- CDC7 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV52312955; called by muse, mutect2, varscan2
- CDH11 | c.1789G>A p.V597M | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.205); catalogued as COSV51758504; called by muse, mutect2, varscan2
- CDH17 | c.92T>A p.L31Q | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50344027; called by muse, mutect2, varscan2
- CDH18 | c.1883-1G>C p.X628_splice | Splice Site (SNP) | VAF 24/134 reads (18%) | catalogued as COSV99938763; called by muse, mutect2, varscan2
- CDH2 | c.2514G>T p.E838D | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.93); catalogued as COSV99298799; called by muse, mutect2, varscan2
- CDH2 | c.1538G>T p.G513V | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as COSV52297979; called by muse, mutect2, varscan2
- CDH2 | c.1195A>T p.I399L | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.028); catalogued as COSV52297986; called by muse, mutect2, varscan2
- CDH2 | c.1097C>A p.A366D | Missense Mutation (SNP) | VAF 34/158 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52297994; called by muse, mutect2, varscan2
- CDH4 | c.710G>T p.R237L | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64676855; called by muse, mutect2, varscan2
- CDH8 | c.875G>T p.G292V | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54903830; called by muse, mutect2, varscan2
- CEACAM19 | c.700G>T p.D234Y | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as COSV100715526; called by muse, mutect2, varscan2
- CELSR1 | c.6191G>A p.W2064* | Nonsense Mutation (SNP) | VAF 10/36 reads (28%) | catalogued as COSV53101054; called by muse, mutect2, varscan2
- CEP164 | c.1798G>T p.A600S | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.359); catalogued as COSV54046937; called by muse, mutect2, varscan2
- CEP350 | c.1267A>G p.T423A | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.019); catalogued as rs1328129317, COSV62610414; called by muse, mutect2
- CERK | c.1141T>A p.W381R | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV53453554; called by muse, mutect2, varscan2
- CLASP2 | c.3830A>T p.H1277L (on ENST00000359576; = p.H1276L on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.309); catalogued as COSV56295179; called by muse, mutect2, varscan2
- CLCN1 | c.2468A>T p.Q823L | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as COSV58374903; called by muse, mutect2, varscan2
- CLCN1 | c.2578G>T p.V860F | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58374909; called by muse, mutect2, varscan2
- CLEC12A | c.488C>T p.A163V | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.291); catalogued as COSV100429719; called by muse, mutect2, varscan2
- CLK4 | c.1219C>T p.R407C | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); catalogued as rs764943317, COSV60321414; called by muse, mutect2, varscan2
- CNDP1 | c.1207A>G p.S403G | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV62595555; called by muse, mutect2, varscan2
- CNTNAP2 | c.1544C>A p.P515H | Missense Mutation (SNP) | VAF 32/160 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as COSV100665202, COSV62265797; called by muse, varscan2
- CNTNAP2 | c.1579G>T p.D527Y | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV62241738, COSV62248392; called by muse, varscan2
- CNTNAP2 | c.1897+1G>T p.X633_splice | Splice Site (SNP) | VAF 11/88 reads (13%) | catalogued as COSV62250414; called by muse, mutect2, varscan2
- CNTNAP4 | c.277G>T p.A93S | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.302); catalogued as COSV56681989, COSV56698811; called by mutect2, varscan2
- COL11A1 | c.4936G>T p.E1646* | Nonsense Mutation (SNP) | VAF 13/73 reads (18%) | catalogued as COSV62173287, COSV62199683; called by muse, mutect2, varscan2
- COL15A1 | c.2575-1G>A p.X859_splice | Splice Site (SNP) | VAF 7/66 reads (11%) | catalogued as COSV66649892; called by muse, mutect2, varscan2
- COL19A1 | c.1479T>A p.D493E | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.072); catalogued as COSV59590094; called by muse, mutect2, varscan2
- COL19A1 | c.2752C>A p.P918T | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV59590102; called by muse, mutect2, varscan2
- COL20A1 | c.588G>T p.Q196H | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV100491624; called by muse, mutect2
- COL24A1 | c.470G>T p.S157I | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.837); catalogued as COSV65315109; called by muse, mutect2, varscan2
- COL3A1 | c.4378G>T p.V1460F | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.694); catalogued as COSV58587268, COSV58597559; called by muse, mutect2, varscan2
- COL6A6 | c.4000G>C p.D1334H | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.459); catalogued as COSV62039115; called by muse, mutect2, varscan2
- COLQ | c.895G>T p.V299L | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as COSV67526206; called by muse, mutect2, varscan2
- CORO2B | c.1133C>A p.A378E | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV55958142; called by muse, mutect2, varscan2
- COX4I1 | c.159G>C p.K53N | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.251); catalogued as COSV53666623; called by muse, mutect2, varscan2
- CPA5 | c.866C>A p.S289* | Nonsense Mutation (SNP) | VAF 4/46 reads (9%) | catalogued as COSV62570933; called by muse, mutect2
- CPED1 | c.2143C>G p.L715V | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.301); catalogued as COSV60014090; called by muse, mutect2, varscan2
- CPNE4 | c.119C>G p.A40G | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as rs944595449, COSV70200752; called by muse, mutect2
- CPS1 | c.1391C>G p.P464R | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51826143; called by muse, mutect2, varscan2
- CPS1 | c.3347T>C p.L1116P | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.879); catalogued as COSV51826156; called by muse, mutect2, varscan2
- CRACD | c.234del p.M79Wfs*4 | Frame Shift Del (DEL) | VAF 7/58 reads (12%) | catalogued as COSV51723337; called by mutect2, pindel, varscan2
- CRACD | c.3178G>T p.G1060W | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV99948949, COSV99949367; called by muse, mutect2
- CRB1 | c.3333A>C p.E1111D | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.978); catalogued as COSV66330267; called by muse, mutect2, varscan2
- CRISPLD1 | c.133G>T p.E45* | Nonsense Mutation (SNP) | VAF 12/65 reads (18%) | catalogued as COSV51553496; called by muse, mutect2, varscan2
- CRNN | c.1001G>A p.G334D | Missense Mutation (SNP) | VAF 24/199 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55124157; called by muse, mutect2, varscan2
- CRTC2 | c.753C>T p.N251= | Splice Region (SNP) | VAF 16/47 reads (34%) | catalogued as rs761929818, COSV57845924; called by muse, mutect2, varscan2
- CSE1L | c.1148G>C p.R383P | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53701583, COSV53705447, COSV53705537; called by muse, mutect2, varscan2
- CSGALNACT2 | c.484G>T p.G162C | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100989860, COSV65676443; called by muse, mutect2, varscan2
- CSMD1 | c.7337A>G p.N2446S (on ENST00000520002; = p.N2445S on NM_033225.6) | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.112); catalogued as COSV59391328; called by muse, mutect2, varscan2
- CSN2 | c.173C>T p.S58F | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV61992806; called by muse, mutect2, varscan2
- CTCF | c.1998G>T p.Q666H | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.585); catalogued as COSV50530478; called by muse, mutect2, varscan2
- CTIF | c.825G>C p.M275I | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV56492584; called by muse, mutect2, varscan2
- CTRC | c.479G>A p.W160* | Nonsense Mutation (SNP) | VAF 27/139 reads (19%) | catalogued as COSV65622159; called by muse, mutect2, varscan2
- CUBN | c.7508C>T p.P2503L | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.059); catalogued as rs140983139; called by muse, mutect2, varscan2
- CXCR2 | c.856T>C p.C286R | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59282273; called by muse, mutect2, varscan2
- CYLC1 | c.840T>A p.Y280* | Nonsense Mutation (SNP) | VAF 7/26 reads (27%) | catalogued as COSV61416427; called by muse, mutect2, varscan2
- CYP2C19 | c.1070G>T p.R357I | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV64909672, COSV64909844; called by muse, mutect2
- CYP2E1 | c.769C>G p.L257V | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as COSV53315660; called by muse, mutect2, varscan2
- CYP46A1 | c.752G>T p.R251L | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55893313, COSV55896930; called by muse, mutect2, varscan2
- DAB2IP | c.3557G>A p.S1186N (on ENST00000408936; = p.S1062N on NM_138709.2) | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as COSV99406088; called by muse, mutect2, varscan2
- DCLK2 | c.433G>T p.V145L | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as rs767818184, COSV56211444, COSV99652834; called by mutect2, varscan2
- DCLRE1A | c.2623G>T p.V875F | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as COSV63749837; called by muse, mutect2, varscan2
- DCSTAMP | c.230A>C p.H77P | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.726); catalogued as COSV52580413; called by muse, mutect2
- DCSTAMP | c.1286C>G p.S429* | Nonsense Mutation (SNP) | VAF 12/61 reads (20%) | catalogued as COSV52580422; called by muse, mutect2, varscan2
- DEFB114 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100435471; called by muse, mutect2, varscan2
- DEFB118 | c.162C>G p.C54W | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53621816; called by muse, mutect2, varscan2
- DHCR24 | c.1188G>C p.Q396H | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.251); catalogued as COSV64875615; called by muse, mutect2, varscan2
- DLG5 | c.1730G>C p.R577P | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64949005, COSV64950230; called by muse, mutect2, varscan2
- DMRT2 | c.976G>A p.V326I | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.987); catalogued as COSV52403977; called by muse, mutect2, varscan2
- DNAAF1 | c.1405C>T p.P469S | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.274); catalogued as COSV57578371; called by muse, mutect2, varscan2
- DNAH12 | c.1264C>T p.L422F | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.117); catalogued as rs1208318644, COSV60856654, COSV60858326; called by muse, mutect2
- DNAH17 | c.11699T>C p.I3900T | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.936); catalogued as rs767669565, COSV67761904; called by muse, mutect2, varscan2
- DNAH5 | c.9275G>C p.G3092A | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54209725, COSV54255649; called by muse, mutect2, varscan2
- DNAI2 | c.691G>T p.V231L | Missense Mutation (SNP) | VAF 50/204 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV56762864; called by muse, mutect2, varscan2
- DNASE1L3 | c.889A>T p.R297W | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV59157594; called by muse, mutect2, varscan2
- DPP10 | c.504G>T p.W168C | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.895); catalogued as COSV100058212; called by muse, mutect2
- DPP6 | c.2530G>T p.V844L (on ENST00000377770 / NM_001364500.2; = p.V782L on NM_001936.5) | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.222); catalogued as COSV59648197; called by muse, mutect2, varscan2
- DPYD | c.2593G>T p.V865F | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs773815814, COSV64616582; called by muse, mutect2, varscan2
- DPYD | c.1483G>A p.D495N | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64616588; called by muse, mutect2, varscan2
- DRD2 | c.1034C>A p.T345N | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV60763368; called by muse, mutect2, varscan2
- DSG2 | c.2293G>C p.V765L | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.63); PolyPhen benign (0.138); catalogued as COSV55203490; called by muse, mutect2
- DUSP10 | c.1392C>A p.N464K | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.076); catalogued as COSV60459953; called by muse, mutect2, varscan2
- DUSP10 | c.295G>T p.A99S | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs773122250, COSV60459008; called by muse, mutect2, varscan2
- DYNC1I1 | c.225G>T p.V75= | Splice Region (SNP) | VAF 23/160 reads (14%) | catalogued as COSV61472404; called by muse, mutect2, varscan2
- DYNC1I1 | c.1276C>T p.P426S | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61472410; called by muse, mutect2
- DYTN | c.185T>A p.L62H | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV71753112; called by muse, mutect2, varscan2
- EBF2 | c.1385C>G p.S462C | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.401); catalogued as COSV68778587; called by muse, mutect2, varscan2
- ECEL1 | c.2119C>A p.H707N | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.191); catalogued as COSV100459076; called by muse, mutect2, varscan2
- EDN3 | c.393C>A p.N131K | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as rs777336048, COSV61110469; called by muse, mutect2, varscan2
- EIF2AK3 | c.337G>T p.G113W | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57552585; called by muse, mutect2, varscan2
- ELMOD1 | c.968C>A p.P323Q | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.731); catalogued as COSV56197308; called by muse, mutect2, varscan2
- ENO3 | c.305A>G p.N102S | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.473); catalogued as COSV56698191; called by muse, mutect2, varscan2
- ENPP2 | c.968C>A p.P323H | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as COSV50042542; called by muse, mutect2, varscan2
- ENTHD1 | c.191A>T p.H64L | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV57325682; called by muse, mutect2, varscan2
- ENTPD2 | c.1149G>C p.Q383H | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs1383258541, COSV57076828; called by muse, mutect2
- EP400 | c.6169G>T p.E2057* | Nonsense Mutation (SNP) | VAF 15/108 reads (14%) | catalogued as COSV57788000; called by muse, mutect2, varscan2
- EPB41L1 | c.1819A>G p.S607G | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.97); catalogued as COSV99152662; called by muse, mutect2, varscan2
- EPHA3 | c.2811C>G p.Y937* | Nonsense Mutation (SNP) | VAF 16/67 reads (24%) | catalogued as COSV60729835; called by muse, mutect2, varscan2
- EPHB6 | c.1690C>G p.R564G | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63893967; called by muse, mutect2, varscan2
- EPX | c.470G>T p.R157I | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV56599646; called by muse, mutect2, varscan2
- ERCC2 | c.722A>T p.N241I | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV55545178; called by muse, mutect2, varscan2
- ERICH3 | c.1344C>A p.N448K | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV58620041; called by muse, mutect2, varscan2
- ETNK1 | c.439A>C p.K147Q | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.475); catalogued as COSV56890107; called by muse, mutect2, varscan2
- EVPL | c.2233G>T p.V745L | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56916669; called by muse, mutect2, varscan2
- EXOC3L2 | c.2158C>A p.L720M | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.69); PolyPhen probably damaging (1); catalogued as COSV52974908; called by muse, mutect2, varscan2
- EXOC8 | c.277G>C p.E93Q | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs762639382, COSV50480070; called by muse, mutect2, varscan2
- F11 | c.151A>C p.T51P | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs281875243, CM080239, COSV53010012; ClinVar: not provided; called by muse, mutect2, varscan2
- F13A1 | c.280G>T p.D94Y | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as rs1203791516, COSV53568602; called by muse, mutect2, varscan2
- F13B | c.1313G>A p.R438H | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as rs192220037, COSV66374039; called by muse, varscan2
- F13B | c.1264G>T p.E422* | Nonsense Mutation (SNP) | VAF 10/66 reads (15%) | catalogued as COSV100803513; called by muse, varscan2
- F5 | c.3382C>A p.Q1128K | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as COSV63121087, COSV63128995; called by muse, mutect2, varscan2
- F9 | c.34C>A p.P12T | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.035); catalogued as COSV54382683; called by muse, mutect2, varscan2
- FAM135B | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs765801243, COSV52732747, COSV99417290; called by muse, mutect2, varscan2
- FAM171B | c.452G>T p.W151L | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100489067; called by muse, mutect2, varscan2
- FAM187B | c.229G>T p.E77* | Nonsense Mutation (SNP) | VAF 36/75 reads (48%) | catalogued as rs762057149, COSV100220098; called by muse, mutect2, varscan2
- FAM78B | c.678G>C p.M226I | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.069); catalogued as COSV57982897; called by muse, mutect2, varscan2
- FAP | c.1138A>G p.I380V | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.76); PolyPhen benign (0.007); catalogued as COSV51868174; called by muse, mutect2, varscan2
- FAT1 | c.5272G>C p.E1758Q | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.543); catalogued as COSV71676212; called by muse, mutect2, varscan2
- FAT2 | c.8233G>T p.D2745Y | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV55830786; called by muse, mutect2, varscan2
- FAT2 | c.4120G>T p.E1374* | Nonsense Mutation (SNP) | VAF 13/59 reads (22%) | catalogued as COSV55830799; called by muse, mutect2, varscan2
- FAT4 | c.14080T>A p.C4694S | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.962); catalogued as COSV58711475; called by muse, mutect2, varscan2
- FBN2 | c.3476T>A p.I1159N | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52547721; called by muse, mutect2, varscan2
- FBN3 | c.8269G>T p.G2757C | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); catalogued as COSV53665291; called by muse, mutect2, varscan2
- FBXL12 | c.683G>T p.R228L | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.206); catalogued as rs375844904, COSV99928010, COSV99928162; called by muse, mutect2, varscan2
- FBXO39 | c.698A>T p.Y233F | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100386115, COSV58623295; called by muse, mutect2, varscan2
- FCGR2A | c.368G>A p.W123* (on ENST00000271450 / NM_001136219.3; = p.W122* on NM_021642.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 38/108 reads (35%) | catalogued as COSV54838638, COSV54841069; called by muse, mutect2, varscan2
- FCGR2B | c.290C>A p.P97H | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV52683404; called by muse, mutect2, varscan2
- FCRL5 | c.1682-1G>T p.X561_splice | Splice Site (SNP) | VAF 14/74 reads (19%) | catalogued as COSV62520914; called by muse, mutect2, varscan2
- FER1L6 | c.2444del p.P815Hfs*14 | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | catalogued as COSV67551700; called by mutect2, pindel
- FERMT1 | c.1265-2A>T p.X422_splice | Splice Site (SNP) | VAF 10/54 reads (19%) | catalogued as COSV99452210, COSV99452226; called by muse, mutect2
- FERMT1 | c.207G>A p.W69* | Nonsense Mutation (SNP) | VAF 6/31 reads (19%) | catalogued as rs1433586125, COSV99452213; called by muse, mutect2, varscan2
- FGD5 | c.2641C>A p.P881T | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.328); catalogued as COSV53237466, COSV53253738; called by muse, mutect2, varscan2
- FGFR2 | c.1259A>T p.K420I | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV60661464; called by muse, mutect2, varscan2
- FHOD3 | c.348C>A p.Y116* | Nonsense Mutation (SNP) | VAF 5/20 reads (25%) | catalogued as COSV57190099; called by muse, mutect2, varscan2
- FIGNL1 | c.83G>T p.G28V | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.117); catalogued as COSV63554156; called by muse, mutect2, varscan2
- FLG | c.11062C>A p.H3688N | Missense Mutation (SNP) | VAF 39/290 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.407); catalogued as COSV100911972, COSV64240363; called by muse, mutect2, varscan2
- FLG | c.7661C>A p.S2554* | Nonsense Mutation (SNP) | VAF 38/262 reads (15%) | catalogued as rs121909626, CM071768, COSV64250905; called by muse, mutect2, varscan2
- FLG2 | c.1366C>G p.H456D | Missense Mutation (SNP) | VAF 37/150 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as COSV66174020; called by muse, mutect2, varscan2
- FN1 | c.2434G>A p.D812N | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV60565335; called by muse, mutect2, varscan2
- FO393400.1 | c.406G>T p.D136Y | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54071708; called by muse, mutect2
- FOXN4 | c.749G>T p.C250F | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54493646; called by muse, varscan2
- FRAS1 | c.6295G>T p.E2099* | Nonsense Mutation (SNP) | VAF 8/52 reads (15%) | catalogued as COSV53665020, COSV99355909; called by muse, mutect2
- FSCB | c.587C>T p.P196L | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.971); catalogued as COSV61219712; called by muse, mutect2, varscan2
- FSCN3 | c.1233G>T p.Q411H | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.123); catalogued as COSV56172109; called by muse, mutect2, varscan2
- FYB1 | c.2104G>T p.D702Y (on ENST00000351578 / NM_199335.5; = p.D748Y on NM_001465.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs1355574545, COSV60957295; called by muse, mutect2
- FZD3 | c.99G>T p.L33F | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV53538026, COSV99527986; called by muse, mutect2, varscan2
- GABRA2 | c.816C>A p.F272L | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62920453; called by muse, mutect2, varscan2
- GABRA4 | c.1480G>T p.G494W | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV51935936, COSV99974875; called by muse, mutect2, varscan2
- GABRE | c.563G>T p.R188M | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64819200; called by muse, mutect2
- GABRR1 | c.1269G>T p.M423I | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as COSV65620907; called by muse, mutect2, varscan2
- GAK | c.3612G>T p.M1204I | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV58503669, COSV58510516; called by muse, mutect2, varscan2
- GALNT17 | c.1448C>A p.P483Q | Missense Mutation (SNP) | VAF 42/230 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.922); catalogued as COSV61194630; called by muse, mutect2
- GANAB | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.082); catalogued as COSV60469009; called by muse, mutect2, varscan2
- GAS7 | c.304+1G>T p.X102_splice (on ENST00000432992 / NM_201433.2; = p.X42_splice on NM_201432.2) | Splice Site (SNP) | VAF 9/50 reads (18%) | catalogued as COSV60444320; called by muse, mutect2, varscan2
- GATA3 | c.1326G>T p.M442I | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.039); catalogued as COSV60520327; called by muse, mutect2, varscan2
- GATA6 | c.1547C>T p.P516L | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as COSV52528239; called by muse, mutect2, varscan2
- GBF1 | c.4669G>T p.A1557S (on ENST00000369983 / NM_001377137.1; = p.A1556S on NM_004193.3) | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.268); catalogued as COSV64149508; called by muse, mutect2, varscan2
- GBP4 | c.1127G>A p.R376K | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV63256211; called by muse, mutect2, varscan2
- GET3 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62002052; called by muse, varscan2
- GGN | c.352C>T p.P118S | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.005); catalogued as COSV53059237; called by muse, mutect2, varscan2
- GGT7 | c.1511C>T p.S504L | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs142938362; called by muse, mutect2, varscan2
- GLRA2 | c.869G>T p.G290V | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54348238; called by muse, mutect2, varscan2
- GLRA4 | c.843G>T p.M281I | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.017); catalogued as COSV65457086; called by muse, mutect2, varscan2
- GNG3 | c.199G>T p.E67* | Nonsense Mutation (SNP) | VAF 12/70 reads (17%) | catalogued as COSV53655700; called by muse, mutect2, varscan2
- GOLGA3 | c.2057G>T p.R686M | Missense Mutation (SNP) | VAF 32/158 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.735); catalogued as COSV52645192; called by muse, mutect2, varscan2
- GOT1L1 | c.829C>G p.Q277E | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV56877943; called by muse, mutect2, varscan2
- GPR132 | c.218A>T p.Q73L | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.934); catalogued as COSV61678444; called by mutect2, varscan2
- GPR32 | c.127C>G p.R43G | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.285); catalogued as COSV54514925, COSV54515776; called by muse, mutect2, varscan2
- GPR50 | c.1658C>A p.P553H | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.19); catalogued as COSV54443326; called by muse, mutect2, varscan2
- GPRC5B | c.1057G>A p.G353S | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs1325542569, COSV56027696; called by muse, mutect2, varscan2
- GRIA1 | c.1279A>C p.N427H | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs371219596; called by muse, mutect2, varscan2
- GRIA3 | c.696+2T>A p.X232_splice | Splice Site (SNP) | VAF 6/45 reads (13%) | catalogued as COSV52074740; called by muse, mutect2, varscan2
- GRIN2A | c.1289T>C p.V430A | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV58058391; called by muse, mutect2, varscan2
- GRIN3A | c.1535A>T p.K512M | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV62458955; called by muse, mutect2, varscan2
- GRM5 | c.868A>G p.M290V | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.967); catalogued as rs775559714, COSV59632406; called by muse, mutect2, varscan2
- GRPR | c.619C>A p.P207T | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV66670349; called by muse, mutect2, varscan2
- GTF3C1 | c.1991G>T p.R664L | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.132); catalogued as COSV62245395; called by muse, mutect2, varscan2
- GUCY1A2 | c.1961G>A p.R654Q | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs201162728, COSV56503874; called by muse, mutect2, varscan2
- H2BC9 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.034); catalogued as rs1561760033, COSV55099491, COSV55099681; called by muse, mutect2
- HDAC9 | c.1251del p.L418Yfs*29 | Frame Shift Del (DEL) | VAF 7/44 reads (16%) | catalogued as COSV67767795; called by mutect2, pindel, varscan2
- HDAC9 | c.2000G>T p.R667L | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101287823, COSV67773704; called by muse, mutect2, varscan2
- HEATR1 | c.1452G>C p.M484I | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as COSV63983370; called by muse, mutect2, varscan2
- HEATR5B | c.2468A>T p.Q823L | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV51859672; called by muse, varscan2
- HEATR5B | c.2403A>C p.L801F | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.25); catalogued as COSV51859682; called by muse, varscan2
- HECTD4 | c.7175G>T p.G2392V | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66396535, COSV66400597; called by muse, mutect2
- HECW1 | c.1297G>A p.V433M | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.121); catalogued as COSV67841148; called by muse, mutect2, varscan2
- HECW2 | c.916A>T p.R306W | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53675952; called by muse, mutect2, varscan2
- HHAT | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.96); catalogued as rs374048677, COSV99802368; called by muse, varscan2
- HIVEP1 | c.6718G>A p.G2240R | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs1167149035, COSV101045111, COSV65105431; called by muse, mutect2, varscan2
- HIVEP3 | c.2957G>T p.R986L | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV56024734; called by muse, mutect2, varscan2
- HLA-DRA | c.708C>G p.I236M | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.622); catalogued as rs770380561, COSV66622548; called by muse, mutect2, varscan2
- HNRNPF | c.716G>T p.G239V | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.53); catalogued as rs1564392711, COSV61562350; called by muse, mutect2, varscan2
- HOXA2 | c.1078G>A p.D360N | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.266); catalogued as COSV99761044; called by muse, mutect2
- HOXB1 | c.299C>A p.P100H | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.122); catalogued as COSV53318860; called by muse, mutect2, varscan2
- HP1BP3 | c.1523A>T p.K508M | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.371); catalogued as COSV56564996; called by muse, mutect2, varscan2
- HPGD | c.493G>T p.A165S | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.151); catalogued as COSV56664660; called by muse, mutect2, varscan2
- HPS4 | c.241A>T p.K81* | Nonsense Mutation (SNP) | VAF 16/41 reads (39%) | catalogued as COSV61106080; called by muse, mutect2, varscan2
- HRC | c.799A>G p.R267G | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765512178, COSV53259207; called by muse, varscan2
- HRH3 | c.446C>A p.T149K | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as rs755605299, COSV58048299, COSV58050728; called by mutect2, varscan2
- HRNR | c.1401C>A p.H467Q | Missense Mutation (SNP) | VAF 34/208 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1412075440, COSV64263439; called by muse, mutect2, varscan2
- HSD17B2 | c.1062G>T p.L354F | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV99556862; called by muse, mutect2, varscan2
- HSD3B2 | c.1016A>G p.Y339C | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM161101, COSV65592755, COSV65594137; called by muse, mutect2, varscan2
- HTR3C | c.435C>A p.S145R | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV59177580; called by muse, mutect2
- HTR6 | c.200C>T p.S67L | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57034832; called by muse, mutect2, varscan2
- HYAL4 | c.20G>T p.G7V | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.072); catalogued as COSV99772509; called by muse, mutect2, varscan2
- HYDIN | c.9389T>A p.I3130N | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV59272415; called by muse, mutect2, varscan2
- IARS2 | c.374G>T p.G125V | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56964628; called by muse, mutect2
- ICAM5 | c.2141G>T p.R714L | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.7); PolyPhen benign (0.217); catalogued as rs765799576, COSV55749558; called by muse, mutect2, varscan2
- IER5 | c.892G>T p.G298C | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV100849713; called by muse, mutect2, varscan2
- IFIT1B | c.305C>G p.A102G | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65663772; called by muse, mutect2, varscan2
- IFT52 | c.612G>T p.K204N | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as COSV65974382; called by muse, mutect2, varscan2
- IGDCC4 | c.2285G>C p.S762T | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.978); catalogued as COSV61539533; called by muse, mutect2, varscan2
- IGF2R | c.6829G>T p.V2277L | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63482385; called by muse, mutect2, varscan2
- IGHG4 | c.712A>T p.M238L | Missense Mutation (SNP) | VAF 15/324 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs371286002; called by muse, mutect2
- IGKV1D-33 | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.116); catalogued as rs760729559, COSV101134097; called by muse, varscan2
- IGSF21 | c.381G>C p.E127D | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated, low confidence (0.35); PolyPhen probably damaging (0.989); catalogued as COSV52145739; called by mutect2, varscan2
- IL12A | c.67G>T p.A23S | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.068); catalogued as COSV59760265; called by muse, mutect2, varscan2
- IL17F | c.178G>T p.G60C | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); catalogued as COSV60235409; called by muse, mutect2, varscan2
- IL1R2 | c.274G>T p.A92S | Missense Mutation (SNP) | VAF 31/204 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.159); catalogued as COSV60209856; called by muse, varscan2
- IL1RL2 | c.1153G>T p.A385S | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51819518; called by muse, mutect2, varscan2
- IL36G | c.258G>C p.L86F | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV52079394; called by muse, mutect2, varscan2
- IL7R | c.664C>A p.P222T | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.933); catalogued as rs1394251315, COSV57410356, COSV57414264; called by muse, mutect2, varscan2
- IMPG1 | c.468G>A p.Q156= | Splice Region (SNP) | VAF 14/48 reads (29%) | catalogued as COSV64062368; called by muse, mutect2, varscan2
- INHBA | c.799G>T p.G267W | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.755); catalogued as COSV54225586; called by muse, mutect2, varscan2
- INTS5 | c.2107G>A p.E703K | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.205); catalogued as COSV57953819; called by muse, mutect2, varscan2
- IPO4 | c.347G>T p.W116L | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55782235; called by muse, mutect2, varscan2
- IRAG2 | c.2989A>G p.I997V (on ENST00000636465; = p.I42V on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs758538532, COSV63137648; called by muse, mutect2, varscan2
- ISL1 | c.196T>A p.Y66N | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV57935942; called by muse, mutect2
- ITIH5 | c.743G>T p.R248M | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.57); catalogued as COSV99906010; called by muse, mutect2, varscan2
- ITIH6 | c.2584C>T p.P862S | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.007); catalogued as COSV54495361; called by muse, mutect2, varscan2
- ITPR2 | c.7254G>T p.K2418N | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV67276954; called by muse, mutect2, varscan2
- JAKMIP3 | c.2170G>T p.E724* | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | catalogued as COSV100059648, COSV100060050; called by muse, mutect2, varscan2
- KANSL1 | c.2699G>T p.S900I (on ENST00000574590 / NM_001193465.2; = p.S901I on NM_015443.4) | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.474); catalogued as COSV52274738; called by muse, mutect2, varscan2
- KCMF1 | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.106); catalogued as rs770915691, COSV69053389; called by muse, mutect2, varscan2
- KCNA10 | c.1507G>T p.G503C | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.125); catalogued as COSV63904445, COSV63905448; called by muse, mutect2, varscan2
- KCNB1 | c.2161C>A p.P721T | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.086); catalogued as COSV65571173; called by muse, mutect2, varscan2
- KCNC2 | c.1513T>A p.S505T | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.517); catalogued as COSV54381257; called by muse, mutect2, varscan2
- KCND1 | c.1757A>T p.D586V | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs201201437, COSV54416272; called by mutect2, varscan2
- KCNG1 | c.125G>A p.R42Q | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as rs1392953285, COSV65370584; called by muse, mutect2, varscan2
- KCNG4 | c.921C>A p.Y307* | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | catalogued as COSV100377205; called by muse, mutect2, varscan2
- KCNK13 | c.687C>A p.Y229* | Nonsense Mutation (SNP) | VAF 10/77 reads (13%) | catalogued as COSV56418270; called by muse, mutect2, varscan2
- KCNN3 | c.1332C>A p.N444K | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.281); catalogued as COSV55227974; called by muse, mutect2, varscan2
- KCNU1 | c.2293C>G p.R765G | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.258); catalogued as COSV101298850, COSV67760205; called by muse, mutect2
- KDM4D | c.1178G>T p.S393I | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.036); catalogued as COSV58636799; called by muse, mutect2, varscan2
- KDR | c.1760G>T p.G587V | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.105); catalogued as COSV55777597; called by muse, mutect2, varscan2
- KEAP1 | c.295G>T p.V99L | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV50275211, COSV50653952; called by muse, mutect2, varscan2
- KIAA0232 | c.1702A>G p.T568A | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV56929850; called by muse, mutect2, varscan2
- KIAA1522 | c.1186C>A p.P396T (on ENST00000373480 / NM_001198972.2; = p.P455T on NM_020888.3) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV99615223; called by muse, mutect2
- KIDINS220 | c.3058G>A p.E1020K | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56750597; called by muse, mutect2, varscan2
- KIF11 | c.1342G>A p.D448N | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV53274459; called by muse, mutect2
- KIF20B | c.1002A>G p.I334M | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.571); catalogued as COSV53316252; called by muse, mutect2, varscan2
- KIF21A | c.4072G>A p.D1358N (on ENST00000361418 / NM_001378440.1; = p.D1345N on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV62778747; called by muse, mutect2, varscan2
- KIF2B | c.247C>A p.L83M | Missense Mutation (SNP) | VAF 28/151 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as rs1229132447, COSV52135985; called by muse, varscan2
- KIF2B | c.358C>A p.P120T | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as COSV52135996; called by muse, varscan2
- KIF2B | c.1951G>T p.A651S | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV52136008; called by muse, mutect2, varscan2
- KIF3C | c.2282G>T p.R761I | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.585); catalogued as COSV53102369, COSV99267165; called by muse, mutect2, varscan2
- KIF6 | c.1810+2T>A p.X604_splice | Splice Site (SNP) | VAF 27/62 reads (44%) | catalogued as COSV54696748; called by muse, mutect2, varscan2
- KIRREL1 | c.1966G>T p.G656C | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as COSV63291885; called by muse, mutect2, varscan2
- KLHL13 | c.1249C>T p.R417* | Nonsense Mutation (SNP) | VAF 17/73 reads (23%) | catalogued as rs368254851, COSV53253744; called by muse, mutect2, varscan2
- KLHL17 | c.586G>T p.G196C | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58532095; called by muse, mutect2, varscan2
- KLK9 | c.537C>A p.Y179* | Nonsense Mutation (SNP) | VAF 27/74 reads (36%) | catalogued as COSV51594967; called by muse, mutect2, varscan2
- KMT2A | c.5048G>C p.R1683P | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV63289356, COSV63293198; called by muse, mutect2, varscan2
- KRT33B | c.1012G>T p.E338* | Nonsense Mutation (SNP) | VAF 11/93 reads (12%) | catalogued as COSV52442704; called by muse, mutect2, varscan2
- KRT5 | c.689T>A p.L230Q | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV52862355; called by muse, mutect2, varscan2
- KRT6B | c.426G>T p.Q142H | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); catalogued as COSV52883936; called by muse, mutect2, varscan2
- KRT79 | c.1494G>T p.K498N | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.42); catalogued as COSV57942558; called by muse, mutect2, varscan2
- KRTAP10-4 | c.1178G>T p.R393L | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); catalogued as rs200036054, COSV100555742; called by muse, mutect2, varscan2
- KRTAP13-4 | c.311C>A p.S104* | Nonsense Mutation (SNP) | VAF 11/25 reads (44%) | catalogued as COSV61880359, COSV61880515; called by muse, mutect2, varscan2
- KRTAP19-4 | c.163G>T p.G55* | Nonsense Mutation (SNP) | VAF 38/126 reads (30%) | catalogued as COSV100478620, COSV61859118; called by muse, mutect2, varscan2
- KRTAP27-1 | c.480A>C p.Q160H | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV67001719; called by muse, mutect2, varscan2
- KTI12 | c.913G>T p.E305* | Nonsense Mutation (SNP) | VAF 16/91 reads (18%) | catalogued as COSV100860284; called by muse, mutect2, varscan2
- L1CAM | c.3322+1G>T p.X1108_splice | Splice Site (SNP) | VAF 22/129 reads (17%) | catalogued as COSV100649499; called by muse, mutect2, varscan2
- L1CAM | c.3322G>A p.G1108S | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV100649500; called by muse, mutect2, varscan2
- LAMA1 | c.3088G>T p.D1030Y | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV67545081; called by muse, mutect2, varscan2
- LAMA1 | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 17/166 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV67539847; called by muse, mutect2, varscan2
- LAMA2 | c.1685A>G p.D562G | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV70356160; called by muse, mutect2, varscan2
- LAMA3 | c.1007G>C p.G336A | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as COSV58082005; called by muse, mutect2, varscan2
- LCE2A | c.188G>C p.G63A | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV64227213; called by muse, mutect2, varscan2
- LDLR | c.1511A>G p.K504R | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV52946285; called by muse, mutect2, varscan2
- LDLRAD2 | c.532C>G p.R178G | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.366); catalogued as COSV60829829; called by mutect2, varscan2
- LMTK3 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.749); catalogued as COSV99541286; called by muse, mutect2, varscan2
- LPA | c.4769C>T p.P1590L | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV60296164; called by muse, mutect2, varscan2
- LPA | c.3935A>T p.Y1312F | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.71); PolyPhen benign (0.309); catalogued as COSV60313738; called by muse, mutect2, varscan2
- LPAR3 | c.496G>T p.G166C | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV65455277; called by muse, mutect2, varscan2
- LRBA | c.478G>C p.A160P | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); catalogued as COSV63966216; called by muse, mutect2
- LRCH4 | c.601C>T p.L201= | Splice Region (SNP) | VAF 9/54 reads (17%) | catalogued as COSV59644871; called by muse, mutect2
- LRGUK | c.1679C>A p.S560Y | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53644648; called by muse, mutect2, varscan2
- LRGUK | c.2447C>A p.T816N | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.367); catalogued as COSV53644658; called by muse, mutect2, varscan2
- LRP1 | c.3960G>T p.K1320N | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV54527923; called by muse, mutect2, varscan2
- LRP5 | c.1419G>T p.M473I | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.975); catalogued as COSV53724465; called by muse, mutect2, varscan2
- LRRIQ1 | c.3910G>T p.A1304S | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as COSV67839574; called by muse, mutect2, varscan2
- LRRIQ1 | c.4360G>T p.D1454Y | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV67830420, COSV67839580; called by muse, mutect2, varscan2
- LRRK2 | c.2897C>T p.S966F | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.166); catalogued as COSV54152917; called by muse, mutect2, varscan2
- LRRN2 | c.1412G>T p.G471V | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.268); catalogued as COSV65784891; called by muse, mutect2, varscan2
- LRRTM4 | c.185G>T p.G62V | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); catalogued as rs1181915406, COSV69139030, COSV69142914; called by muse, mutect2, varscan2
- LTBP1 | c.2788C>A p.R930S (on ENST00000404816 / NM_206943.4; = p.R604S on NM_000627.4) | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.81); catalogued as rs774681859, COSV63193526, COSV63198756; called by muse, mutect2, varscan2
- LYST | c.7515A>G p.I2505M | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.203); catalogued as COSV67714951; called by muse, mutect2, varscan2
- LYST | c.629C>T p.T210I | Missense Mutation (SNP) | VAF 35/167 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.347); catalogued as COSV67714958; called by muse, mutect2, varscan2
- LZTR1 | c.1429G>C p.A477P | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV53152235; called by muse, mutect2, varscan2
- MAGEA11 | c.1136C>A p.P379H | Missense Mutation (SNP) | VAF 36/192 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV60755845, COSV60759205; called by muse, mutect2, varscan2
- MAGEB16 | c.794T>A p.V265E | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67874704; called by muse, mutect2, varscan2
- MAGI2 | c.563C>A p.P188Q | Missense Mutation (SNP) | VAF 31/203 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1474048312, COSV62692019, COSV62702289; called by muse, mutect2, varscan2
- MAN2A1 | c.2687T>G p.L896R | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54859297; called by muse, mutect2, varscan2
- MARCHF10 | c.1103C>A p.S368Y | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV60890775; called by muse, mutect2, varscan2
- MARCHF11 | c.883A>C p.I295L | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.688); catalogued as COSV60133393, COSV60135694; called by muse, mutect2, varscan2
- MARCO | c.1476G>T p.E492D | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59056952, COSV59059274; called by muse, mutect2, varscan2
- MAT2B | c.182G>T p.R61I | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.119); catalogued as COSV55202544; called by muse, mutect2, varscan2
- MBD4 | c.1516C>G p.L506V | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV51446023; called by muse, mutect2, varscan2
- MCM6 | c.2402G>A p.G801E | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV51469760; called by muse, mutect2, varscan2
- MCRS1 | c.147C>A p.S49= | Splice Region (SNP) | VAF 17/100 reads (17%) | catalogued as COSV59461894; called by muse, mutect2, varscan2
- MDGA2 | c.2696C>A p.P899H (on ENST00000399232 / NM_001113498.2; = p.P601H on NM_182830.4) | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.141); catalogued as COSV100637326, COSV100638657; called by muse, mutect2
- MED12L | c.2721-1G>T p.X907_splice | Splice Site (SNP) | VAF 37/250 reads (15%) | catalogued as COSV56399729; called by muse, mutect2, varscan2
- MED15 | c.130C>T p.H44Y | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV99488274; called by muse, mutect2, varscan2
- MET | c.3703T>C p.Y1235H | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59257036, COSV59270155; called by muse, mutect2, varscan2
- MFSD1 | c.688T>A p.L230M | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV51843641; called by muse, mutect2, varscan2
- MFSD1 | c.780G>C p.K260N | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.842); catalogued as COSV51843655, COSV99964137; called by muse, mutect2
- MLXIPL | c.2422C>G p.L808V | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57668689; called by muse, mutect2, varscan2
- MMP27 | c.586G>C p.D196H | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52782998; called by muse, mutect2, varscan2
- MNDA | c.353C>A p.A118E | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as COSV63742225; called by muse, mutect2, varscan2
- MNDA | c.473C>A p.P158H | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.888); catalogued as COSV63742228; called by muse, mutect2, varscan2
- MNDA | c.815C>A p.S272Y | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as COSV63742231; called by muse, mutect2, varscan2
- MPHOSPH6 | c.59A>C p.Q20P | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99259392; called by muse, mutect2, varscan2
- MRC1 | c.1159G>T p.A387S | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781920426, COSV53471342; called by muse, mutect2, varscan2
- MROH2B | c.1453C>A p.Q485K | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101270951; called by muse, mutect2
- MROH7 | c.2429G>C p.C810S | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.389); catalogued as COSV59878604; called by muse, mutect2, varscan2
- MROH8 | c.1698T>C p.F566= | Splice Region (SNP) | VAF 12/74 reads (16%) | catalogued as COSV54125741; called by muse, varscan2
- MRPL39 | c.268A>G p.S90G | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.038); catalogued as COSV100221132; called by muse, mutect2, varscan2
- MRPL47 | c.373C>G p.P125A | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.978); catalogued as COSV52024162; called by muse, mutect2, varscan2
- MRPS30 | c.418G>T p.A140S | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.218); catalogued as COSV72361955; called by muse, mutect2, varscan2
- MTMR12 | c.849A>T p.K283N | Missense Mutation (SNP) | VAF 39/143 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.617); catalogued as COSV53788452; called by muse, mutect2, varscan2
- MTNR1A | c.442G>A p.V148M | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as rs762288381, COSV56156348; called by muse, mutect2, varscan2
- MTOR | c.3840G>T p.W1280C | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV63879000; called by muse, mutect2, varscan2
- MTPAP | c.1219G>T p.D407Y | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.45); catalogued as COSV53936481; called by muse, mutect2, varscan2
- MUC16 | c.8910G>T p.M2970I | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs371915094, COSV101201962; called by muse, mutect2, varscan2
- MUC16 | c.8909T>A p.M2970K | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.087); catalogued as COSV101201963; called by muse, mutect2, varscan2
- MUC16 | c.3424G>T p.D1142Y | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.146); catalogued as COSV67453516, COSV67497716; called by muse, mutect2, varscan2
- MUC16 | c.2522C>T p.P841L | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV67497723; called by muse, mutect2, varscan2
- MUC3A | c.8885G>T p.G2962V | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100115546; called by muse, mutect2
- MUC7 | c.190A>G p.K64E | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0.011); catalogued as COSV59220321; called by muse, mutect2, varscan2
- MUC7 | c.493A>G p.T165A | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.119); catalogued as COSV59220328; called by muse, mutect2, varscan2
- MX1 | c.1715C>G p.S572C | Missense Mutation (SNP) | VAF 41/209 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV55820188, COSV55821151; called by muse, mutect2, varscan2
- MYBPC1 | c.2731C>A p.L911M (on ENST00000550270 / NM_206820.2; = p.L918M on NM_002465.4) | Missense Mutation (SNP) | VAF 28/171 reads (16%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.503); catalogued as rs1303927391, COSV62258106; called by muse, mutect2, varscan2
- MYBPC1 | c.2956C>A p.H986N (on ENST00000550270 / NM_206820.2; = p.H993N on NM_002465.4) | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1429394527, COSV62258118; called by muse, mutect2, varscan2
- MYEF2 | c.1457G>A p.R486K | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV51054061; called by muse, mutect2, varscan2
- MYH2 | c.2484G>T p.M828I | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.095); catalogued as COSV55449898; called by muse, mutect2, varscan2
- MYH6 | c.4639G>C p.E1547Q | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62454996; called by muse, mutect2, varscan2
- MYO1D | c.2317G>A p.E773K | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as COSV59017910, COSV59024713; called by muse, mutect2
- MYO3A | c.666G>T p.E222D | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56351501; called by muse, mutect2, varscan2
- MYO3A | c.1230G>T p.M410I | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV56351518; called by muse, mutect2, varscan2
- MYO3A | c.3201A>T p.R1067S | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV56351536; called by muse, mutect2, varscan2
- MYO3B | c.1262A>G p.Q421R | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.139); catalogued as COSV58719729; called by muse, mutect2, varscan2
- MYO9B | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV68282564, COSV68283193; called by muse, mutect2, varscan2
- MYOM2 | c.2273A>T p.H758L | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV50786591; called by muse, mutect2
- MYT1L | c.1052C>A p.P351Q | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.001); catalogued as COSV67726585, COSV67733928; called by muse, mutect2, varscan2
- NANOS1 | c.741C>A p.Y247* | Nonsense Mutation (SNP) | VAF 9/34 reads (26%) | catalogued as COSV100403998; called by muse, mutect2, varscan2
- NAV3 | c.3924C>A p.S1308R | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV57115110; called by muse, mutect2, varscan2
- NAV3 | c.5596C>A p.P1866T (on ENST00000397909 / NM_001024383.2; = p.P1844T on NM_014903.6) | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.242); catalogued as COSV57115122; called by muse, mutect2, varscan2
- NAV3 | c.6641T>C p.I2214T (on ENST00000397909 / NM_001024383.2; = p.I2192T on NM_014903.6) | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57115135; called by muse, mutect2, varscan2
- NBR1 | c.2321A>T p.Q774L | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV57835995; called by muse, mutect2
- NCK2 | c.913G>T p.E305* | Nonsense Mutation (SNP) | VAF 6/28 reads (21%) | catalogued as COSV51896924; called by muse, mutect2, varscan2
- NCKAP5 | c.3185G>T p.G1062V | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.503); catalogued as COSV58478244; called by muse, mutect2
- NEFM | c.1279C>T p.R427* | Nonsense Mutation (SNP) | VAF 8/38 reads (21%) | catalogued as rs1246789788, COSV55331661, COSV99647270; called by muse, mutect2, varscan2
- NES | c.1318G>T p.V440F | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); catalogued as COSV63960446, COSV63963116; called by muse, mutect2, varscan2
- NETO1 | c.472C>A p.P158T | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs750589525, COSV55009842; called by muse, mutect2, varscan2
- NEU4 | c.1448C>A p.P483H (on ENST00000391969 / NM_001167602.3; = p.P495H on NM_080741.4) | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.79); catalogued as COSV57992221; called by muse, mutect2, varscan2
- NEUROD4 | c.811C>A p.P271T | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.94); catalogued as COSV54472934, COSV54474437; called by muse, varscan2
- NLGN2 | c.556G>T p.G186C | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57212478; called by muse, mutect2, varscan2
- NLRP9 | c.914C>A p.S305* | Nonsense Mutation (SNP) | VAF 27/75 reads (36%) | catalogued as COSV60459687, COSV60463018, COSV60468327; called by muse, mutect2, varscan2
- NLRX1 | c.872G>T p.R291L | Missense Mutation (SNP) | VAF 33/157 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52710329; called by muse, mutect2, varscan2
- NOC4L | c.343A>C p.K115Q | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.034); catalogued as COSV57960330; called by muse, mutect2
- NOC4L | c.345G>T p.K115N | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.621); catalogued as COSV100223105; called by muse, mutect2
- NOMO1 | c.1220G>T p.G407V | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.036); catalogued as COSV99814937; called by muse, mutect2, varscan2
- NOP14 | c.1100G>T p.G367V | Missense Mutation (SNP) | VAF 32/179 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV58628194; called by muse, mutect2, varscan2
- NOS2 | c.2306C>A p.P769Q | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58227866; called by muse, mutect2, varscan2
- NOTCH4 | c.1004C>G p.S335C | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.536); catalogued as rs772628389, COSV66684270; called by muse, mutect2, varscan2
- NOVA1 | c.659T>C p.V220A | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.932); catalogued as COSV57488798; called by muse, mutect2, varscan2
- NPAP1 | c.3313G>A p.D1105N | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.012); catalogued as COSV61512008; called by muse, mutect2, varscan2
- NPBWR2 | c.938C>A p.P313H | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100871153; called by muse, mutect2
- NPY1R | c.720G>T p.R240S | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.363); catalogued as COSV56713810, COSV56716699; called by muse, mutect2, varscan2
- NPY5R | c.1036G>A p.D346N | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as rs1408874008, COSV58454141; called by muse, mutect2, varscan2
- NR4A2 | c.1232C>T p.T411I | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as rs772578858, COSV59895878; called by muse, mutect2, varscan2
- NRG1 | c.632+1G>A p.X211_splice | Splice Site (SNP) | VAF 12/59 reads (20%) | catalogued as COSV99829796; called by muse, mutect2, varscan2
- NRG1 | c.1126G>A p.V376I (on ENST00000405005 / NM_013964.5; = p.V381I on NM_013956.5) | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as rs757580752, COSV55172230; called by muse, mutect2, varscan2
- NRXN1 | c.2111G>T p.G704V | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.25); catalogued as COSV58497698; called by muse, mutect2, varscan2
- NRXN2 | c.2444G>A p.G815E | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as COSV55464471; called by muse, varscan2
- NTM | c.549C>A p.D183E | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.24); catalogued as COSV66196172; called by muse, mutect2, varscan2
- NUTF2 | c.91G>C p.A31P | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.204); catalogued as COSV54647638, COSV99534612; called by muse, mutect2, varscan2
- NYNRIN | c.3202C>T p.P1068S | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1367891668, COSV66843474; called by muse, mutect2, varscan2
- OPN1SW | c.586C>A p.R196S | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.255); catalogued as COSV99975956; called by muse, mutect2, varscan2
- OR10A4 | c.841G>T p.V281L | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.777); catalogued as COSV101139523, COSV65842653; called by muse, mutect2, varscan2
- OR10J3 | c.508T>A p.C170S | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59955758; called by mutect2, varscan2
- OR10R2 | c.829T>A p.F277I | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV63769639; called by mutect2, varscan2
- OR10T2 | c.829A>G p.T277A | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.381); catalogued as COSV57783842; called by muse, mutect2, varscan2
- OR10Z1 | c.377T>C p.I126T | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV63526716; called by muse, mutect2, varscan2
- OR13C5 | c.742G>T p.V248L | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1169175282, COSV66165419; called by muse, mutect2, varscan2
- OR14K1 | c.104C>A p.T35K | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.018); catalogued as COSV99315527; called by muse, mutect2, varscan2
- OR2A2 | c.821C>A p.S274Y | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); catalogued as COSV101286666, COSV101286679; called by muse, mutect2, varscan2
- OR2AE1 | c.130C>T p.L44F | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV100318434; called by muse, mutect2, varscan2
- OR2AK2 | c.286G>T p.G96C | Missense Mutation (SNP) | VAF 30/189 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV63562216; called by muse, mutect2, varscan2
- OR2G2 | c.432C>A p.C144* | Nonsense Mutation (SNP) | VAF 33/193 reads (17%) | catalogued as COSV60742550; called by muse, mutect2, varscan2
- OR2G2 | c.862C>G p.L288V | Missense Mutation (SNP) | VAF 30/194 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as COSV60742558; called by muse, mutect2, varscan2
- OR2G3 | c.180C>G p.Y60* | Nonsense Mutation (SNP) | VAF 41/284 reads (14%) | catalogued as COSV60683437; called by muse, mutect2, varscan2
- OR2G6 | c.133C>A p.L45I | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100598251, COSV100598347; called by muse, mutect2, varscan2
- OR2M2 | c.73A>T p.T25S | Missense Mutation (SNP) | VAF 43/225 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.04); catalogued as COSV62899530; called by muse, mutect2, varscan2
- OR2M4 | c.193C>T p.Q65* | Nonsense Mutation (SNP) | VAF 17/144 reads (12%) | catalogued as COSV60709870; called by muse, mutect2, varscan2
- OR2M5 | c.932G>T p.G311V | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.393); catalogued as COSV100822729, COSV63547115, COSV63547144; called by muse, mutect2, varscan2
- OR2T1 | c.733A>C p.T245P | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as COSV63543008; called by muse, mutect2, varscan2
- OR4A16 | c.791C>A p.P264H | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as COSV59045309; called by muse, mutect2, varscan2
- OR4C13 | c.685G>C p.E229Q | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.314); catalogued as rs782565308, COSV73648963; called by muse, mutect2, varscan2
- OR4C16 | c.341T>A p.I114N | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV58944538; called by muse, mutect2
- OR4C6 | c.781G>C p.V261L | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.152); catalogued as COSV58606307, COSV58606592; called by muse, mutect2, varscan2
- OR4D11 | c.136A>T p.M46L | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV57587334; called by muse, mutect2, varscan2
- OR4K5 | c.282C>A p.F94L | Missense Mutation (SNP) | VAF 16/312 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV60003613, COSV60005449; called by muse, mutect2
- OR4S2 | c.602G>T p.S201I | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV56748535; called by muse, mutect2, varscan2
- OR51L1 | c.928G>C p.V310L | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV58625969; called by muse, mutect2, varscan2
- OR51V1 | c.547C>A p.L183M | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV100343540; called by muse, mutect2, varscan2
- OR52L1 | c.62C>G p.S21* | Nonsense Mutation (SNP) | VAF 7/29 reads (24%) | catalogued as COSV100176224, COSV59989549; called by muse, mutect2, varscan2
- OR5F1 | c.689C>A p.S230* | Nonsense Mutation (SNP) | VAF 9/32 reads (28%) | catalogued as rs762358931, COSV53545988, COSV53549109; called by muse, mutect2, varscan2
- OR5I1 | c.553C>G p.P185A | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.579); catalogued as COSV100041741; called by mutect2, varscan2
- OR5J2 | c.389T>A p.L130* | Nonsense Mutation (SNP) | VAF 13/78 reads (17%) | catalogued as COSV56623493; called by muse, mutect2, varscan2
- OR5L1 | c.107G>A p.G36E | Missense Mutation (SNP) | VAF 35/201 reads (17%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.642); catalogued as COSV61735572; called by muse, mutect2, varscan2
- OR5P3 | c.193C>T p.H65Y | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.242); catalogued as COSV100103291; called by muse, mutect2, varscan2
- OR5T2 | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.089); catalogued as COSV57588829, COSV57591186; called by muse, mutect2, varscan2
- OR6K3 | c.484G>T p.A162S (on ENST00000368146; = p.A146S on NM_001005327.2) | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.309); catalogued as COSV63746650; called by muse, mutect2, varscan2
- OR6N1 | c.65G>A p.G22D | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV58648736, COSV58650655; called by muse, mutect2, varscan2
- OR6Q1 | c.801G>T p.K267N | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.06); catalogued as COSV56934848; called by muse, mutect2, varscan2
- OR6T1 | c.392G>T p.R131L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as rs765590865, COSV100190091, COSV58307265; called by muse, mutect2
- OR8H3 | c.417G>C p.R139S | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.515); catalogued as COSV57911924; called by muse, mutect2, varscan2
- OR8K3 | c.427G>T p.V143L | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.019); catalogued as COSV57131600; called by muse, mutect2, varscan2
- OR9G4 | c.259T>A p.S87T | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.98); catalogued as COSV57250049; called by muse, mutect2, varscan2
- OSTN | c.62G>T p.S21I | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.548); catalogued as COSV100174372; called by muse, mutect2, varscan2
- OTOF | c.2846C>A p.P949H (on ENST00000272371 / NM_194248.3; = p.P202H on NM_004802.4) | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55522207; called by muse, mutect2, varscan2
- OTOF | c.1392G>A p.K464= | Splice Region (SNP) | VAF 6/36 reads (17%) | catalogued as COSV55522238; called by muse, mutect2, varscan2
- OTOGL | c.629C>A p.T210K (on ENST00000547103; = p.T201K on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.426); catalogued as COSV101509526; called by muse, mutect2, varscan2
- OTOGL | c.3445A>C p.N1149H (on ENST00000547103; = p.N1140H on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); catalogued as COSV101509527; called by muse, mutect2
- OTUD5 | c.1235G>T p.R412L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); catalogued as COSV50240462; called by muse, mutect2
- OXGR1 | c.548G>T p.C183F | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53658728; called by muse, mutect2, varscan2
- OXGR1 | c.186G>C p.M62I | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.134); catalogued as COSV53658739; called by muse, mutect2, varscan2
- OXTR | c.587G>T p.G196V | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57481227; called by muse, mutect2, varscan2
- P2RX5 | c.534-1G>T p.X178_splice | Splice Site (SNP) | VAF 30/113 reads (27%) | catalogued as COSV56594061; called by muse, mutect2, varscan2
- P2RY1 | c.857C>T p.A286V | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.429); catalogued as COSV100521809; called by muse, mutect2, varscan2
- PABPC5 | c.1139G>C p.R380P | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV57040246, COSV57043472; called by muse, mutect2
- PAK5 | c.798G>T p.R266S | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as rs987695739, COSV62039052; called by muse, mutect2
- PAK5 | c.796A>T p.R266W | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as COSV62030910; called by muse, mutect2
- PAN2 | c.2890A>T p.M964L (on ENST00000425394 / NM_001127460.3; = p.M960L on NM_014871.5) | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV56265312; called by muse, mutect2, varscan2
- PAPPA2 | c.4085G>T p.R1362L | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV62802802, COSV62813164; called by muse, mutect2, varscan2
- PAQR3 | c.679G>C p.G227R | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55011550, COSV55012269; called by muse, mutect2, varscan2
- PARD3B | c.3163G>T p.E1055* (on ENST00000406610 / NM_001302769.2; = p.E986* on NM_057177.7) | Nonsense Mutation (SNP) | VAF 20/129 reads (16%) | catalogued as COSV62532803; called by muse, mutect2, varscan2
- PASK | c.549C>A p.S183R | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as COSV52161730; called by mutect2, varscan2
- PATJ | c.1964C>G p.S655C | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.237); catalogued as COSV57173010; called by muse, mutect2, varscan2
- PAX6 | c.669G>T p.E223D | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.168); catalogued as COSV99570857; called by muse, mutect2
- PBX1 | c.1028C>G p.S343C | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as COSV63348543; called by muse, mutect2
- PCDH15 | c.4627G>T p.G1543C (on ENST00000644397 / NM_001354429.2; = p.G1492C on NM_001142769.3) | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as COSV64743262; called by muse, mutect2, varscan2
- PCDH15 | c.191G>T p.G64V | Missense Mutation (SNP) | VAF 49/186 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV57403315; called by muse, mutect2, varscan2
- PCDHA12 | c.1535C>T p.A512V | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV56550700; called by muse, mutect2, varscan2
- PCDHA13 | c.506C>A p.T169N | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.155); catalogued as COSV56550708; called by muse, mutect2, varscan2
- PCDHA3 | c.309C>A p.S103R | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.18); catalogued as COSV65371574; called by muse, mutect2, varscan2
- PCDHAC1 | c.2013G>C p.W671C | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV53872604; called by muse, mutect2
- PCDHAC2 | c.1796del p.P599Lfs*10 | Frame Shift Del (DEL) | VAF 12/33 reads (36%) | catalogued as COSV53858240; called by mutect2, pindel, varscan2
- PCDHB13 | c.291C>A p.C97* | Nonsense Mutation (SNP) | VAF 12/83 reads (14%) | catalogued as COSV99507145, COSV99507945; called by muse, mutect2, varscan2
- PCDHB2 | c.1953G>T p.E651D | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.029); catalogued as COSV50585476, COSV99166879; called by muse, mutect2, varscan2
- PCDHB4 | c.836G>T p.G279V | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs782644748, COSV52027550; called by muse, mutect2, varscan2
- PCDHB7 | c.1162G>T p.D388Y | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.334); catalogued as COSV50762150, COSV50823479; called by muse, mutect2, varscan2
- PCDHB8 | c.1405C>G p.L469V | Missense Mutation (SNP) | VAF 76/434 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as COSV50753833, COSV50823483; called by muse, varscan2
- PCDHGA3 | c.1456C>G p.R486G | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); catalogued as COSV54043962; called by muse, mutect2, varscan2
- PCDHGA8 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.367); catalogued as rs1308893775, COSV54044002; called by muse, mutect2, varscan2
- PCDHGB5 | c.2332G>T p.G778C | Missense Mutation (SNP) | VAF 47/152 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.353); catalogued as COSV54044017; called by muse, mutect2, varscan2
- PCLO | c.13132G>T p.A4378S | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV61671420; called by muse, mutect2, varscan2
- PCLO | c.12131G>A p.R4044Q | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1271626427, COSV61619046; called by muse, mutect2, varscan2
- PCSK2 | c.919G>T p.A307S | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52744438; called by muse, mutect2, varscan2
- PDE1A | c.169G>T p.E57* | Nonsense Mutation (SNP) | VAF 15/61 reads (25%) | catalogued as COSV59517417, COSV59538393; called by muse, mutect2, varscan2
- PDE3A | c.3020A>G p.H1007R | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62983715; called by muse, mutect2, varscan2
- PDE4D | c.131G>C p.R44P | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.986); catalogued as rs774486077, COSV72353481, COSV72355966; called by muse, mutect2, varscan2
- PDE8B | c.682C>A p.P228T | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV53746696; called by muse, mutect2, varscan2
- PDPR | c.185C>G p.S62C | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as COSV55357378; called by muse, mutect2, varscan2
- PEG3 | c.228G>T p.Q76H | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55649404; called by muse, mutect2, varscan2
- PEX5 | c.1917G>T p.Q639H (on ENST00000420616; = p.Q631H on NM_000319.5) | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.917); catalogued as COSV56958802; called by muse, mutect2
- PEX5L | c.904G>T p.A302S | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as COSV55858795; called by muse, mutect2
- PGM5 | c.1465G>A p.V489M | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV101124100; called by muse, mutect2
- PGR | c.2497G>T p.E833* | Nonsense Mutation (SNP) | VAF 16/50 reads (32%) | catalogued as COSV54811632, COSV99679246; called by muse, varscan2
- PIGG | c.2803A>G p.I935V (on ENST00000453061 / NM_001127178.3; = p.I927V on NM_017733.4) | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as rs1205693775, COSV56321870; called by muse, mutect2, varscan2
- PIGO | c.1645G>T p.V549F | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.139); catalogued as COSV53055704; called by muse, mutect2, varscan2
- PIGV | c.403C>T p.H135Y | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1389087489, COSV99315182; called by muse, mutect2
- PIP5K1B | c.1363G>C p.G455R | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV55258939; called by muse, mutect2, varscan2
- PKD1L1 | c.2520C>A p.H840Q | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.254); catalogued as COSV56979719; called by muse, mutect2, varscan2
- PKD2L1 | c.1238G>A p.R413Q | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0.111); catalogued as rs145997401, COSV58394861; called by muse, mutect2, varscan2
- PKHD1L1 | c.8590C>A p.L2864I | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as COSV65754664; called by muse, mutect2, varscan2
- PKP2 | c.426G>T p.R142S | Missense Mutation (SNP) | VAF 50/256 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.07); catalogued as COSV99298583; called by muse, mutect2, varscan2
- PKP2 | c.425G>T p.R142M | Missense Mutation (SNP) | VAF 51/259 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV50736430, COSV99298189; called by muse, mutect2, varscan2
- PLB1 | c.2294C>A p.T765N | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0.401); catalogued as COSV59836780; called by muse, mutect2, varscan2
- PLCG2 | c.2470G>A p.V824I | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs776078043, COSV63873821, COSV63874116; called by muse, mutect2, varscan2
- PLD1 | c.1847G>T p.G616V | Missense Mutation (SNP) | VAF 70/161 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.282); catalogued as COSV60574782; called by muse, mutect2, varscan2
- PLEKHG3 | c.3109G>C p.G1037R (on ENST00000394691; = p.G1093R on NM_001308147.2) | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV55984380; called by muse, mutect2
- PLG | c.2024C>T p.A675V | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.626); catalogued as rs755339005, COSV57521728; called by muse, mutect2
- PNMA8B | c.1555G>A p.E519K | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.033); catalogued as rs955053105, COSV66537868; called by muse, mutect2, varscan2
- PNPLA5 | c.854G>A p.R285H | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs144693499, COSV53376278; called by muse, mutect2, varscan2
- POLG | c.2391G>C p.M797I | Missense Mutation (SNP) | VAF 111/222 reads (50%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.596); catalogued as COSV51525676; called by muse, mutect2, varscan2
- POLR2A | c.3007G>A p.D1003N | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.645); catalogued as rs1385388168; called by muse, mutect2, varscan2
- POLR3A | c.3312A>T p.R1104S | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV64932246; called by muse, mutect2
- POLR3B | c.3098G>C p.R1033T | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57285231, COSV99944039; called by muse, mutect2
- POM121L12 | c.466C>A p.Q156K | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.427); catalogued as COSV68692265, COSV68693332; called by muse, mutect2, varscan2
- POMGNT2 | c.1321G>T p.E441* | Nonsense Mutation (SNP) | VAF 6/25 reads (24%) | catalogued as COSV100768167; called by muse, mutect2, varscan2
- POSTN | c.753A>T p.R251S | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.124); catalogued as COSV65714905; called by muse, mutect2, varscan2
- PPP1R9A | c.2815G>T p.G939C | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV56913157; called by muse, mutect2, varscan2
- PRB1 | c.157C>A p.P53T | Missense Mutation (SNP) | VAF 34/210 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.35); catalogued as COSV53705661, COSV53706982; called by muse, mutect2, varscan2
- PRDM4 | c.668C>T p.S223F | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV57307859, COSV99946756; called by muse, mutect2, varscan2
- PRKCG | c.1373+1G>A p.X458_splice | Splice Site (SNP) | VAF 16/43 reads (37%) | catalogued as COSV54731417; called by muse, mutect2, varscan2
- PRRC2C | c.8208G>T p.Q2736H (on ENST00000367742; = p.Q2734H on NM_015172.4) | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV58914310; called by muse, mutect2, varscan2
- PSG9 | c.1016C>T p.P339L | Missense Mutation (SNP) | VAF 64/112 reads (57%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.971); catalogued as rs1011981509, COSV52488885; called by muse, mutect2, varscan2
- PSMD1 | c.95A>G p.N32S | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs1463955143, COSV58076290; called by muse, mutect2
- PTGS1 | c.1574G>C p.G525A | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV56295114, COSV99793484; called by muse, mutect2, varscan2
- PTK2 | c.1550G>T p.S517I | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.563); catalogued as COSV61793622; called by muse, mutect2, varscan2
- PTPDC1 | c.1146A>T p.Q382H (on ENST00000375360 / NM_177995.3; = p.Q434H on NM_152422.4) | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV99997982; called by muse, mutect2, varscan2
- PTPN13 | c.5191G>T p.D1731Y (on ENST00000411767 / NM_080683.3; = p.D1712Y on NM_006264.3) | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV57418655; called by muse, mutect2, varscan2
- PTPRB | c.4434C>G p.F1478L | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54255277; called by muse, mutect2, varscan2
- PTPRC | c.319C>A p.P107T | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as COSV100722739, COSV61421309; called by muse, mutect2, varscan2
- PTPRD | c.1160C>A p.S387* | Nonsense Mutation (SNP) | VAF 21/117 reads (18%) | catalogued as COSV61933056, COSV61985585; called by muse, mutect2, varscan2
- PUM2 | c.2056A>C p.S686R | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.667); catalogued as COSV57585858; called by muse, mutect2, varscan2
- RAB5A | c.232G>C p.G78R | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56086268; called by muse, mutect2, varscan2
- RASA1 | c.1261del p.D421Tfs*3 | Frame Shift Del (DEL) | VAF 7/32 reads (22%) | catalogued as COSV57197332; called by mutect2, pindel, varscan2
- RBM48 | c.447A>T p.K149N | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.214); catalogued as COSV50422100; called by muse, mutect2
- REG3A | c.287G>C p.G96A | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV59412221; called by muse, mutect2, varscan2
- RELCH | c.2414A>T p.E805V | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.676); catalogued as COSV56893238; called by muse, mutect2, varscan2
- RELN | c.746G>T p.R249L | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV59032269, COSV59036571; called by muse, mutect2, varscan2
- RETREG1 | c.898G>C p.E300Q (on ENST00000306320 / NM_001034850.2; = p.E159Q on NM_019000.4) | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100105079; called by muse, mutect2, varscan2
- RETREG1 | c.451A>T p.S151C | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); catalogued as COSV60452497; called by muse, mutect2
- RFPL4B | c.373G>T p.D125Y | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs769985727, COSV101480733, COSV71437071; called by muse, mutect2, varscan2
- RGL1 | c.2267G>T p.R756L (on ENST00000360851 / NM_001297672.2; = p.R791L on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.814); catalogued as COSV58997329; called by muse, mutect2, varscan2
- RGS1 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.357); catalogued as COSV66506666; called by muse, mutect2, varscan2
- RIMS2 | c.1412G>C p.R471P (on ENST00000666250 / NM_001348490.2; = p.R279P on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51661684, COSV51728533; called by muse, mutect2, varscan2
- RIMS2 | c.2930A>G p.Y977C (on ENST00000666250 / NM_001348490.2; = p.Y785C on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.983); catalogued as COSV51728563; called by muse, mutect2, varscan2
- RIPK1 | c.1241G>T p.R414M | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV52531977; called by muse, mutect2, varscan2
- RLF | c.1173G>T p.K391N | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV65653363; called by muse, mutect2, varscan2
- RNF133 | c.293C>T p.S98L | Missense Mutation (SNP) | VAF 31/234 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.315); catalogued as COSV57388420; called by muse, mutect2, varscan2
- RNF138 | c.593G>T p.G198V | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.762); catalogued as COSV55235918; called by muse, mutect2, varscan2
- RNF180 | c.527G>A p.G176E | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.634); catalogued as COSV56965719; called by muse, mutect2, varscan2
- RNPEPL1 | c.1060G>C p.E354Q | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54374143; called by muse, mutect2, varscan2
- ROR1 | c.214G>T p.G72C | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64293825; called by muse, mutect2, varscan2
- RP1 | c.5680A>G p.S1894G | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV55128159; called by muse, mutect2, varscan2
- RPIA | c.787G>C p.D263H | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV52171994; called by muse, mutect2, varscan2
- RPL37 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.376); catalogued as COSV57037606, COSV57038604; called by muse, mutect2, varscan2
- RPL4 | c.895C>A p.Q299K | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as COSV57183607; called by muse, mutect2, varscan2
- RPS6KC1 | c.2230C>A p.H744N | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as COSV65303098; called by muse, mutect2, varscan2
- RSRC2 | c.1124A>T p.K375M | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59207232; called by muse, mutect2, varscan2
- RTTN | c.416A>G p.E139G | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.036); catalogued as COSV55352897; called by muse, mutect2, varscan2
- RUNX3 | c.795C>G p.D265E | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100137139; called by muse, mutect2, varscan2
- RYR3 | c.2546T>C p.F849S | Missense Mutation (SNP) | VAF 54/117 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66809997; called by muse, mutect2, varscan2
- RYR3 | c.3005G>A p.G1002E | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66810001; called by muse, mutect2, varscan2
- RYR3 | c.11014G>C p.E3672Q (on ENST00000389232; = p.E3673Q on NM_001036.6) | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV66810010; called by muse, mutect2, varscan2
- S1PR4 | c.704A>G p.Q235R | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99859478; called by muse, mutect2, varscan2
- SAGE1 | c.401A>C p.Q134P | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV61018649; called by muse, mutect2, varscan2
- SALL3 | c.3591G>T p.Q1197H | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV73306649; called by muse, mutect2, varscan2
- SALL4 | c.1214C>A p.T405N | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53856610; called by muse, mutect2, varscan2
- SAMHD1 | c.1249del p.E417Kfs*6 | Frame Shift Del (DEL) | VAF 15/79 reads (19%) | catalogued as COSV53428938; called by mutect2, pindel, varscan2
- SART3 | c.848C>A p.T283K (on ENST00000228284; = p.T265K on NM_014706.4) | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57210898; called by muse, mutect2, varscan2
- SATB1 | c.1356G>T p.L452F | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV58669340, COSV58669395, COSV58673160; called by muse, mutect2, varscan2
- SBK1 | c.336G>T p.K112N | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV59399232; called by muse, mutect2, varscan2
- SCIN | c.1423C>T p.Q475* (on ENST00000297029 / NM_001112706.3; = p.Q228* on NM_033128.3) | Nonsense Mutation (SNP) | VAF 10/26 reads (38%) | catalogued as COSV51699505; called by muse, mutect2, varscan2
- SCN1A | c.4473G>C p.K1491N (on ENST00000303395 / NM_001202435.3; = p.K1480N on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as COSV57689984; called by muse, mutect2, varscan2
- SCN3A | c.3922G>A p.A1308T | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51826054, COSV99328292; called by muse, mutect2, varscan2
- SELE | c.781A>G p.S261G | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.338); catalogued as COSV60978019; called by muse, mutect2, varscan2
- SELENON | c.1388-1G>T p.X463_splice | Splice Site (SNP) | VAF 20/87 reads (23%) | catalogued as CS083978, COSV62526485; called by muse, mutect2, varscan2
- SEMA3A | c.382C>G p.H128D | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54880829; called by muse, mutect2, varscan2
- SEMA3D | c.1767C>A p.D589E | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0.015); catalogued as COSV52406290; called by muse, mutect2, varscan2
- SERTAD3 | c.79C>T p.Q27* | Nonsense Mutation (SNP) | VAF 8/21 reads (38%) | catalogued as COSV100475205; called by muse, varscan2
- SETD1A | c.2234G>T p.R745L | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.034); catalogued as COSV52686132, COSV52693145; called by muse, mutect2, varscan2
- SFT2D2 | c.413G>T p.W138L | Missense Mutation (SNP) | VAF 54/223 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV54801062; called by muse, mutect2, varscan2
- SH3PXD2A | c.2914G>T p.V972L (on ENST00000369774 / NM_001365079.1; = p.V944L on NM_014631.2) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.97); catalogued as COSV60121016; called by muse, mutect2, varscan2
- SHPRH | c.548G>A p.G183D | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.05); catalogued as rs753564922, COSV51618467; called by muse, mutect2, varscan2
- SI | c.4343C>A p.T1448K | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV100017410; called by muse, mutect2
- SI | c.1151C>A p.T384K | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV52303397; called by muse, mutect2, varscan2
- SIAH2 | c.857G>T p.G286V | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100469479; called by muse, mutect2, varscan2
- SIM1 | c.314C>T p.S105L | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53497305; called by muse, mutect2, varscan2
- SIPA1L2 | c.2519A>T p.K840M | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV53401192; called by muse, mutect2, varscan2
- SLC10A2 | c.721G>T p.G241W | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753750767, COSV99808329; called by muse, mutect2, varscan2
- SLC10A6 | c.91G>T p.E31* | Nonsense Mutation (SNP) | VAF 9/51 reads (18%) | catalogued as COSV56723602; called by muse, mutect2
- SLC12A1 | c.2473C>A p.L825I | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV66800362; called by muse, mutect2, varscan2
- SLC13A3 | c.1490A>G p.E497G | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51723935; called by muse, mutect2, varscan2
- SLC22A12 | c.572C>A p.A191D | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV60574326; called by muse, mutect2, varscan2
- SLC25A47 | c.394C>G p.Q132E | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.83); PolyPhen benign (0.071); catalogued as COSV64162455; called by mutect2, varscan2
- SLC2A9 | c.1419G>T p.Q473H | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53329707; called by muse, mutect2
- SLC35B1 | c.713C>T p.S238F (on ENST00000649906; = p.S201F on NM_005827.4) | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV53604490; called by muse, mutect2, varscan2
- SLC38A11 | c.857T>A p.V286E (on ENST00000409149 / NM_001351539.1; = p.V264E on NM_173512.2) | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV58056362; called by muse, mutect2, varscan2
- SLC38A4 | c.119+2T>A p.X40_splice | Splice Site (SNP) | VAF 40/208 reads (19%) | catalogued as COSV56971789; called by muse, mutect2, varscan2
- SLC39A12 | c.1012C>A p.P338T | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66202854; called by muse, mutect2, varscan2
- SLC4A3 | c.143G>C p.G48A | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated, low confidence (0.22); PolyPhen probably damaging (0.992); catalogued as rs1382468943, COSV56098015; called by muse, mutect2
- SLC5A5 | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs1395675137, COSV55835897; called by muse, mutect2, varscan2
- SLC5A8 | c.615A>G p.I205M | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV73311259; called by muse, mutect2, varscan2
- SLC7A14 | c.2273A>G p.E758G | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.034); catalogued as COSV51591133; called by muse, mutect2, varscan2
- SLC8A1 | c.1108C>A p.R370S | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60493942, COSV60498021; called by muse, mutect2, varscan2
- SLC8A2 | c.318G>C p.E106D | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.941); catalogued as COSV52643279; called by muse, mutect2, varscan2
- SLIT2 | c.2143+2T>C p.X715_splice | Splice Site (SNP) | VAF 11/66 reads (17%) | catalogued as COSV56558382; called by muse, mutect2, varscan2
- SMAD1 | c.770G>A p.R257K | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV57471671; called by muse, mutect2, varscan2
- SMC6 | c.1441G>T p.G481C | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61178782; called by muse, mutect2, varscan2
- SNTG1 | c.1234C>A p.L412I | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV52475839; called by muse, mutect2, varscan2
- SNX31 | c.1225C>T p.Q409* | Nonsense Mutation (SNP) | VAF 25/120 reads (21%) | catalogued as rs780750524, COSV61265188; called by muse, mutect2, varscan2
- SORCS1 | c.415G>T p.E139* | Nonsense Mutation (SNP) | VAF 8/56 reads (14%) | catalogued as COSV53862580, COSV53909266; called by muse, mutect2, varscan2
- SORCS3 | c.2032C>T p.R678C | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1448976588, COSV100863881; called by muse, mutect2, varscan2
- SORCS3 | c.2033G>T p.R678L | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as rs146574756, COSV100863884; called by mutect2, varscan2
- SOWAHB | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as COSV57555599; called by muse, mutect2, varscan2
- SPAG16 | c.587G>T p.R196L | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs201426260, COSV55990206; called by muse, mutect2
- SPAG17 | c.4692G>T p.E1564D | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as COSV100310839; called by muse, mutect2, varscan2
- SPAG6 | c.929G>T p.R310L | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.11); catalogued as rs573352808, COSV100510625, COSV57624523; called by muse, mutect2
- SPATA16 | c.15C>A p.S5R | Missense Mutation (SNP) | VAF 12/155 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); catalogued as COSV100651747; called by muse, mutect2
- SPDL1 | c.1564G>T p.V522L | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs143182474, COSV54669985; called by muse, varscan2
- SPDL1 | c.1624G>C p.A542P | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV54669994; called by muse, varscan2
- SPEF2 | c.1041G>T p.R347S | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99214978; called by muse, mutect2, varscan2
- SPEF2 | c.1591A>G p.I531V | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.651); catalogued as rs756792876, COSV61554229; called by muse, mutect2, varscan2
- SPEG | c.8729C>A p.P2910Q | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.648); catalogued as COSV56680795; called by muse, mutect2, varscan2
- SPEG | c.8905C>A p.L2969M | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.832); catalogued as COSV100405823, COSV56680805; called by muse, mutect2, varscan2
- SPHKAP | c.3193C>A p.P1065T | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV60882570, COSV60896018; called by muse, mutect2, varscan2
- SPRR2B | c.17A>G p.Q6R | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.484); catalogued as COSV100482354; called by muse, mutect2, varscan2
- SPTA1 | c.4003C>G p.R1335G | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as COSV63754837, COSV63760532; called by mutect2, varscan2
- SPTB | c.205G>T p.A69S | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.035); catalogued as rs1204232304, COSV101072113; called by muse, mutect2
- SPTBN2 | c.283C>T p.L95F | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59462076; called by muse, mutect2, varscan2
- SRPK1 | c.1654G>C p.E552Q | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100644453, COSV60416623; called by muse, mutect2, varscan2
- ST3GAL2 | c.955G>C p.E319Q | Missense Mutation (SNP) | VAF 6/53 reads (11%) | PolyPhen probably damaging (0.977); catalogued as COSV61598430; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.125A>T p.Q42L | Missense Mutation (SNP) | VAF 12/69 reads (17%) | PolyPhen benign (0.049); catalogued as COSV60351613; called by muse, mutect2, varscan2
- STAB2 | c.6005C>A p.P2002Q | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV66348032; called by muse, mutect2, varscan2
- STMN3 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100899889, COSV64246820; called by muse, mutect2, varscan2
- STXBP1 | c.937A>T p.S313C | Missense Mutation (SNP) | VAF 32/155 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV64815663; called by muse, mutect2, varscan2
- SULT1C3 | c.863A>T p.D288V | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.422); catalogued as COSV61254751; called by muse, mutect2
- SWT1 | c.618G>T p.W206C | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV62259597; called by muse, mutect2, varscan2
- SYCP2 | c.609G>T p.M203I | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV62773018; called by muse, mutect2, varscan2
- SYNE2 | c.8327T>C p.L2776P | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV59972349; called by muse, mutect2, varscan2
- SYT14 | c.494C>A p.P165Q | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.024); catalogued as COSV99656270; called by muse, mutect2
- SYT16 | c.703G>A p.G235R | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1413075127, COSV70855944; called by muse, mutect2, varscan2
- TACC2 | c.1642G>T p.G548W | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV57775222; called by muse, mutect2, varscan2
- TAL1 | c.714C>A p.F238L | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.876); catalogued as COSV53748952; called by muse, mutect2, varscan2
- TANGO6 | c.2215G>A p.E739K | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs760111026, COSV55773611; called by muse, mutect2, varscan2
- TAS1R2 | c.2447T>C p.L816P | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV64747497; called by muse, mutect2
- TAS1R3 | c.1342G>T p.G448* | Nonsense Mutation (SNP) | VAF 4/30 reads (13%) | catalogued as rs143311630, COSV100229914; called by mutect2, varscan2
- TBCC | c.171C>A p.S57R | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV99774033; called by muse, mutect2, varscan2
447 further variants in this file (162 protein-altering or splice-affecting, 262 silent, 23 other) are not listed here.
